Somatic mutation profile of tumor specimen TCGA-14-1451-01A (aliquot TCGA-14-1451-01A-01W-0611-08) from TCGA case TCGA-14-1451, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 39.4 years (14,401 days).
Specimen TCGA-14-1451-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c090bf76-bd98-496d-a06b-8bdad9611b78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-1451-10A (Blood Derived Normal), aliquot TCGA-14-1451-10A-01W-0612-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36ad595b-6ee6-4ee4-b4fe-17dac6149f7a

The open-access MAF lists 32 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 18, Silent 9, Nonsense Mutation 2, Frame Shift Del 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.741dup p.P248Tfs*5 | Frame Shift Ins (INS) | VAF 421/780 reads (54%) | catalogued as rs587782341, CI043805, COSV64288762; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACOT4 | c.623T>C p.F208S | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100412860; called by muse, mutect2, varscan2
- ALG10B | c.751T>G p.F251V | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100439907; called by muse, mutect2
- ATP6V1B1 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1485968139, COSV99314149; called by muse, mutect2, varscan2
- CALCR | c.1252G>A p.V418M (on ENST00000649521 / NM_001164737.2; = p.V402M on NM_001742.4) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as rs774211263, COSV64007153, COSV64009997; called by muse, mutect2, varscan2
- CRYBG1 | c.2573C>T p.T858I | Missense Mutation (SNP) | VAF 238/602 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.142); catalogued as COSV100954480; called by muse, mutect2, varscan2
- CSH2 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 144/327 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs375686495; called by muse, mutect2, varscan2
- DNAH11 | c.12646G>T p.E4216* | Nonsense Mutation (SNP) | VAF 22/426 reads (5%) | catalogued as COSV100179365; called by muse, mutect2
- EIF2B2 | c.512C>G p.S171C | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM031174, COSV99837687; called by muse, mutect2, varscan2
- EYA3 | c.256T>A p.S86T | Missense Mutation (SNP) | VAF 89/197 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.292); catalogued as COSV100870254; called by muse, mutect2, varscan2
- F13A1 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 241/564 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.722); catalogued as rs747218826, COSV53553411; called by muse, mutect2, varscan2
- FBXL22 | c.102G>T p.R34S | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.041); catalogued as COSV100634412; called by muse, mutect2, varscan2
- FRK | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 154/472 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.908); catalogued as rs1306029667, COSV101606652; called by muse, mutect2, varscan2
- GBE1 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs565408717, COSV101450161; called by muse, mutect2, varscan2
- KCNV1 | c.572del p.T191Mfs*39 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as COSV52085541; called by mutect2, pindel, varscan2
- LTF | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 217/502 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as rs573693534, COSV51608776; called by muse, mutect2, varscan2
- MUC16 | c.25553C>T p.T8518I | Missense Mutation (SNP) | VAF 187/433 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.205); catalogued as rs1295890922, COSV67456535, COSV67497663; called by muse, mutect2, varscan2
- OR6N1 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as rs553756004, COSV58648333; called by muse, mutect2, varscan2
- PAM | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs776407655, COSV57212094; called by muse, mutect2, varscan2
- RBMS2 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.101); catalogued as rs1325231314, COSV100008536; called by muse, mutect2, varscan2
- WDR38 | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV100793830; called by muse, mutect2, varscan2
- YAP1 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 41/766 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as COSV99176130; called by muse, mutect2
- SWSAP1 | c.618_620del p.M206del (on ENST00000312423; = p.M227del on NM_175871.4) | In Frame Del (DEL) | VAF 14/50 reads (28%) | called by pindel, varscan2
- CDH7 | c.357G>A p.T119= | Silent (SNP) | VAF 39/115 reads (34%) | catalogued as rs201657602, COSV59881319, COSV59883575; called by muse, mutect2, varscan2
- DRC7 | c.258C>A p.T86= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV100395654; called by muse, mutect2
- GATA6 | c.1377C>T p.A459= | Silent (SNP) | VAF 59/119 reads (50%) | catalogued as rs765639422, COSV99333197; called by muse, mutect2, varscan2
- HLA-E | c.162C>T p.F54= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100931919; called by muse, mutect2, varscan2
- KCNH8 | c.1125C>T p.Y375= | Silent (SNP) | VAF 240/609 reads (39%) | catalogued as rs781283040, COSV60482272; called by muse, mutect2, varscan2
- NPSR1 | c.507C>T p.I169= | Silent (SNP) | VAF 65/209 reads (31%) | catalogued as rs760343674, COSV100706145; called by muse, mutect2, varscan2
- RBBP6 | c.2082G>A p.S694= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs1285888084, COSV100154618; called by muse, mutect2, varscan2
- TOP3B | c.1335G>A p.K445= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100592509; called by muse, mutect2
- TRIM22 | c.1110C>T p.G370= | Silent (SNP) | VAF 78/212 reads (37%) | catalogued as COSV66091070; called by muse, mutect2, varscan2
